FM case AD7013 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Epithelial Neoplasms; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/402a821c-f329-4500-b2c5-ee28084ee7e6

Male, 66.2 years: Adenosquamous carcinoma (ICD-O-3 8560/3) of the lung; metastasis biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
